Gene-level copy-number profile of tumor specimen BLGSP-71-27-00420-01A from CGCI case BLGSP-71-27-00420, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 55.8 years (20,374 days).
Specimen BLGSP-71-27-00420-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b889b666-21f2-4e1c-b8f5-b0d618f5dd9c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-27-00420-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,735 have no estimate.
https://portal.gdc.cancer.gov/files/0f2cd3a0-859f-4e43-9437-f84fe803a5e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 674; copy number 1: 3,486; copy number 2: 48,532; copy number 3: 5,934; copy number 4: 151; copy number 5: 17; copy number 9: 14; copy number 12: 80.

Homozygous deletions (total copy number 0; autosomes only): 162 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,254,015, 37 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr4:9,239,130–9,250,222, 3 genes (within-gene range 0–2): USP17L16P, USP17L17, USP17L18.
- chr14:105,672,308–106,481,706, 120 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 111 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:143,368,876–143,419,150, 3 genes, copy number 5: RHPN1, AC105118.1, MAFA-AS1.
- chr12:9,852,984–9,932,370, 4 genes, copy number 5: CLEC2B, AC091814.1, KLRF2, CLEC2A.
- chr12:26,905,181–27,014,434, 4 genes, copy number 5: INTS13, FGFR1OP2, TM7SF3, AC024896.1.
- chr14:22,112,347–22,552,156, 94 genes, copy number 9–12 (broad region; genes not listed).
- chr14:60,212,462–60,299,087, 3 genes, copy number 5: RPL17P2, AL157756.1, PPM1A.
- chr14:61,529,128–61,657,964, 1 gene, copy number 5 (within-gene range 3–5): AL355916.3.
- chr14:61,556,273–61,658,696, 2 genes, copy number 5: LINC01303, AL355916.1.

Autosomal genes at a single copy (total copy number 1): 1,142. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
